Gene-level copy-number profile of tumor specimen TCGA-S9-A7R8-01A from TCGA case TCGA-S9-A7R8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.6 years (16,275 days).
Specimen TCGA-S9-A7R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.680d2dbf-4fc2-444c-a72a-9b12ae15d036.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S9-A7R8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d9bcd90-5e67-4179-8d2c-6a71e65e79d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,968; copy number 2: 52,086; copy number 3: 1,842; copy number 4: 904; copy number 5: 8; copy number 6: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S9-A7R8-01A-11D-A34I-01): tumor purity 0.87, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,199,823–10,295,579, 8 genes, copy number 5: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr12:114,104,542–114,105,931, 1 gene, copy number 6: GLULP5.
- chr14:53,169,010–53,991,995, 10 genes, copy number 6 (within-gene range 4–6): AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1.

Autosomal genes at a single copy (total copy number 1): 4,959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
